Somatic mutation profile of tumor specimen 0DI7V7 from CCDI case PBBRGU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 15.4 years (5,609 days).
Specimen 0DI7V7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3ac4074-0ced-4267-90ee-f94ff3d64fb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI7VD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfd0a0c4-ea2c-4309-b14c-2eea8fb2fa79

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 2, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.2110G>A p.A704T (on ENST00000297504 / NM_001282291.2; = p.A687T on NM_007188.5) | Missense Mutation (SNP) | VAF 60/828 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs778555833, COSV52509320; called by muse, mutect2
- ADGRD1 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 261/645 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs189007948; called by muse, mutect2, varscan2
- B3GNT9 | c.180C>G p.D60E | Missense Mutation (SNP) | VAF 43/403 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV54627953; called by muse, mutect2, varscan2
- MAP3K4 | c.3283G>A p.G1095R | Missense Mutation (SNP) | VAF 71/707 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- S1PR4 | c.1078A>C p.S360R | Missense Mutation (SNP) | VAF 121/480 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HK2 | c.1746C>T p.I582= | Silent (SNP) | VAF 42/1006 reads (4%) | catalogued as rs181541956; called by muse, mutect2
- HBS1L | c.-71G>T | 5'UTR (SNP) | VAF 39/158 reads (25%) | called by muse, mutect2, varscan2
- KRT2 | c.*41C>A | 3'UTR (SNP) | VAF 77/504 reads (15%) | called by muse, mutect2, varscan2
- OR4A47 | c.*33C>A | 3'UTR (SNP) | VAF 22/274 reads (8%) | catalogued as COSV101487123; called by muse, mutect2
